Gene-level copy-number profile of tumor specimen ALCH-B36I-TTP1-A from ALCHEMIST case ALCH-B36I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.7 years (27,639 days).
Specimen ALCH-B36I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 45b43da2-2606-4c9d-a383-770396d1b774.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36I-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/d29f06ac-b06e-426c-a1a3-bfc45a4c8ee4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 2,044; copy number 2: 54,203; copy number 3: 1,840; copy number 4: 140; copy number 5: 69; copy number 6: 9; copy number 7: 51; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:107,028,199–107,051,586, 1 gene: MTRES1.
- chr7:74,487,428–74,487,540, 1 gene (within-gene range 0–2): RNA5SP233.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–2): NEK6, AL162724.2, AL162724.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr12:109,880,676–109,888,467, 1 gene: AC007834.1.
- chr14:92,923,150–92,935,285, 1 gene: CHGA.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr17:16,438,767–16,492,193, 6 genes (within-gene range 0–2): SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:46,762,506–46,833,154, 1 gene: WNT3.
- chr19:41,386,374–41,397,359, 1 gene (within-gene range 0–2): EXOSC5.
- chr19:54,953,130–55,001,142, 2 genes (within-gene range 0–2): NLRP2, AC011476.1.
- chr20:31,485,778–31,645,006, 11 genes: LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2.
- chr22:41,229,510–41,240,931, 1 gene (within-gene range 0–1): CHADL.
- chr22:41,252,992–41,253,050, 1 gene (within-gene range 0–1): MIR6889.
- chr22:41,377,177–41,446,801, 3 genes (within-gene range 0–1): RNU6-495P, AL008582.1, TOB2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:133,778,246–133,778,699, 2 genes, copy number 10: RPL23AP60, BX322534.1.
- chr12:57,253,762–58,920,504, 59 genes, copy number 5 (within-gene range 2–5): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3.
- chr12:61,708,259–62,279,150, 6 genes, copy number 7 (within-gene range 4–7): TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1.
- chr12:62,260,359–62,260,454, 1 gene, copy number 7 (within-gene range 4–7): MIR6125.
- chr12:64,507,001–64,697,564, 1 gene, copy number 6 (within-gene range 2–6): RASSF3.
- chr12:64,575,665–64,710,513, 8 genes, copy number 6: SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1.
- chr12:65,758,020–66,066,338, 9 genes, copy number 5: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362.
- chr12:68,686,951–68,745,809, 1 gene, copy number 7 (within-gene range 4–7): NUP107.
- chr12:68,746,125–70,637,440, 43 genes, copy number 7: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr18:78,976,555–78,979,074, 1 gene, copy number 5: LINC01896.

Autosomal genes at a single copy (total copy number 1): 650. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
